Somatic mutation profile of tumor specimen TCGA-CV-7407-01A (aliquot TCGA-CV-7407-01A-11D-2078-08) from TCGA case TCGA-CV-7407, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 67.0 years (24,475 days).
Specimen TCGA-CV-7407-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a225cea7-4e44-47df-85e6-bb4793fe0802.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7407-10A (Blood Derived Normal), aliquot TCGA-CV-7407-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a53378fc-1fb3-443a-9c44-4c8bcf258e08

The open-access MAF lists 125 somatic variants for this specimen: 88 protein-altering or splice-affecting, 34 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 34, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 2, Frame Shift Ins 1, 3'UTR 1, 5'Flank 1, Splice Region 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.738G>A p.M246I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1019340046, COSV52735934, COSV52772732, COSV53038458, COSV53481758; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACACA | c.2846C>A p.P949H | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); catalogued as rs371689992; called by muse, mutect2, varscan2
- ADCY2 | c.908C>A p.A303E | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100602900; called by muse, mutect2, varscan2
- ADGRG4 | c.5566C>G p.P1856A | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99795473; called by muse, mutect2, varscan2
- AKT3 | c.407C>G p.S136C | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV55630148, COSV99795396; called by muse, mutect2, varscan2
- ANGEL2 | c.560A>G p.Y187C | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751644663, COSV100853952; called by muse, mutect2, varscan2
- ANKLE2 | c.1295C>T p.S432L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.673); catalogued as rs771035135, COSV61709248; called by muse, mutect2, varscan2
- ARHGAP30 | c.2662G>T p.V888L | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV100920266; called by muse, mutect2, varscan2
- ARHGEF12 | c.3164A>T p.D1055V | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100754920; called by muse, mutect2, varscan2
- ARR3 | c.218A>T p.K73I | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100330879; called by muse, mutect2, varscan2
- ATP1B4 | c.577C>G p.L193V (on ENST00000218008 / NM_001142447.3; = p.L189V on NM_012069.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.134); catalogued as rs1012019749, COSV99486356; called by muse, mutect2, varscan2
- CACNG5 | c.335T>G p.F112C | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99400592; called by muse, mutect2, varscan2
- CCDC105 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.626); catalogued as COSV52965978; called by muse, mutect2
- CCDC121 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.6); catalogued as COSV99270174; called by muse, mutect2, varscan2
- CD1D | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs199860570, COSV63809742; called by muse, mutect2, varscan2
- COBLL1 | c.1592C>G p.T531R (on ENST00000392717; = p.T493R on NM_014900.5) | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99527915; called by muse, mutect2, varscan2
- CUX1 | c.139G>T p.E47* (on ENST00000292535 / NM_181552.4; = p.E58* on NM_001913.5) | Nonsense Mutation (SNP) | VAF 7/63 reads (11%) | catalogued as COSV99471512; called by muse, mutect2
- DNAJC10 | c.1363G>A p.V455I | Missense Mutation (SNP) | VAF 22/325 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.936); catalogued as COSV99899248; called by muse, mutect2
- DOCK2 | c.5382C>A p.D1794E | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.235); catalogued as COSV99912421; called by muse, mutect2, varscan2
- DSCAM | c.3689A>G p.Y1230C | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.75); catalogued as COSV101260147; called by muse, mutect2, varscan2
- DSCAM | c.1358A>G p.H453R | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as rs754761952, COSV101260150; called by mutect2, varscan2
- ERG | c.34A>G p.I12V | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV101296608; called by muse, mutect2
- EYA1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58160674; called by muse, mutect2, varscan2
- F5 | c.3018T>G p.H1006Q | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as COSV100889103; called by muse, mutect2
- FANCC | c.775G>T p.E259* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100002459; called by muse, mutect2, varscan2
- FBXL13 | c.1250C>G p.S417C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.019); catalogued as COSV100501622; called by muse, mutect2, varscan2
- FER | c.1135G>C p.A379P | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV99812798; called by muse, mutect2, varscan2
- GPR158 | c.1515G>T p.R505S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV100893552; called by muse, mutect2, varscan2
- GPR63 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.212); catalogued as COSV100013345; called by mutect2, varscan2
- GRM8 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100282975; called by muse, mutect2, varscan2
- H1-6 | c.560C>T p.A187V | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.037); catalogued as rs1211173123, COSV100619546; called by muse, mutect2, varscan2
- IL18RAP | c.1451A>G p.N484S | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.48); PolyPhen benign (0.033); catalogued as COSV99961979; called by mutect2, varscan2
- ITIH4 | c.379C>T p.Q127* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99819391; called by muse, mutect2, varscan2
- LCT | c.3626A>C p.Y1209S | Missense Mutation (SNP) | VAF 48/156 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV51557471, COSV99929494; called by muse, mutect2, varscan2
- LRP1B | c.5432C>A p.P1811H | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.628); catalogued as COSV101257023; called by muse, mutect2, varscan2
- LRRC8D | c.1889G>C p.S630T | Missense Mutation (SNP) | VAF 6/75 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.334); catalogued as COSV100487257; called by muse, mutect2
- METTL3 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV99398293; called by muse, mutect2, varscan2
- MRPL16 | c.141A>C p.K47N | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.425); catalogued as COSV100276490; called by muse, mutect2
- MS4A15 | c.641G>A p.S214N (on ENST00000405633 / NM_001098835.2; = p.S121N on NM_152717.3) | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.045); catalogued as rs779694586, COSV61961260; called by muse, mutect2, varscan2
- MYH8 | c.5443A>G p.I1815V | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.031); catalogued as COSV101238404; called by muse, mutect2, varscan2
- NCKAP1 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 5/143 reads (3%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.982); catalogued as COSV100720247; called by muse, mutect2
- NCOR1 | c.4682G>A p.R1561Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs953868639, COSV99249896; called by muse, mutect2, varscan2
- NINL | c.1263G>A p.M421I | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV99625347; called by mutect2, varscan2
- NRAP | c.3766G>A p.E1256K (on ENST00000359988 / NM_001322945.2; = p.E1221K on NM_006175.4) | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764226845, COSV100748439; called by muse, mutect2, varscan2
- ONECUT2 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV72153049; called by muse, mutect2, varscan2
- OR4N2 | c.113T>C p.I38T | Missense Mutation (SNP) | VAF 22/316 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0.042); catalogued as COSV60051614; called by muse, mutect2
- PBX4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs147300531; called by muse, mutect2, varscan2
- PCDHA1 | c.1565C>T p.P522L | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); catalogued as COSV100974360, COSV100974598; called by muse, mutect2, varscan2
- PFKL | c.237+1G>T p.X79_splice | Splice Site (SNP) | VAF 6/26 reads (23%) | catalogued as COSV100827158; called by muse, mutect2, varscan2
- PLEKHM2 | c.2796C>G p.Y932* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99606613; called by muse, mutect2, varscan2
- PLXDC2 | c.358A>G p.I120V | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated (0.35); PolyPhen benign (0.024); catalogued as rs1386705680, COSV101022960; called by muse, mutect2, varscan2
- PMFBP1 | c.883C>T p.P295S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.094); catalogued as rs752533522, COSV52829409; called by muse, mutect2
- POLE | c.4126G>T p.E1376* | Nonsense Mutation (SNP) | VAF 9/62 reads (15%) | catalogued as COSV100266703; called by muse, mutect2
- PRCC | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 96/299 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.313); catalogued as COSV99618694; called by muse, mutect2, varscan2
- PSMB4 | c.651C>A p.C217* | Nonsense Mutation (SNP) | VAF 25/177 reads (14%) | catalogued as COSV99305025; called by muse, mutect2, varscan2
- RICTOR | c.3550A>C p.K1184Q | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.346); catalogued as COSV99704938; called by muse, mutect2, varscan2
- RTN1 | c.511A>G p.T171A | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV99955664; called by muse, mutect2, varscan2
- SECISBP2 | c.1119A>T p.E373D | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.029); catalogued as COSV100368666; called by muse, mutect2, varscan2
- SEMA5A | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV101228241; called by muse, mutect2, varscan2
- SERTAD4 | c.414G>C p.R138S | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.38); catalogued as rs1399866594, COSV100882614; called by muse, mutect2, varscan2
- SFI1 | c.3194C>G p.S1065* (on ENST00000400288 / NM_001007467.3; = p.S1034* on NM_014775.4) | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV56718889; called by muse, mutect2, varscan2
- SLC26A8 | c.2374G>A p.V792M | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.058); catalogued as rs115071158; called by muse, mutect2, varscan2
- SLC4A3 | c.506G>A p.G169E | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV99812836; called by muse, mutect2, varscan2
- SLC5A4 | c.207G>A p.P69= | Splice Region (SNP) | VAF 32/70 reads (46%) | catalogued as rs937336878, COSV99831919, COSV99832053; called by muse, mutect2, varscan2
- SYNE2 | c.5107A>G p.I1703V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs775006855, COSV100647674; called by muse, mutect2, varscan2
- TCEAL8 | c.65G>A p.R22H | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs1278456291, COSV100749822; called by muse, mutect2
- TCTE1 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs374735103, COSV65255452; called by muse, mutect2, varscan2
- TFEC | c.674T>G p.I225S | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV99624485; called by muse, mutect2, varscan2
- TNRC6A | c.4786C>T p.R1596C | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs760467705, COSV59368699; called by muse, mutect2, varscan2
- TRRAP | c.8824G>A p.E2942K (on ENST00000359863 / NM_001244580.1; = p.E2924K on NM_003496.3) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722488; called by muse, mutect2, varscan2
- TSGA10 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV100747544; called by muse, mutect2, varscan2
- TTN | c.71966G>A p.G23989E (on ENST00000591111; = p.G16565E on NM_003319.4) | Missense Mutation (SNP) | VAF 20/456 reads (4%) | PolyPhen probably damaging (1); catalogued as COSV100612772; called by muse, mutect2
- VPS33B | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 38/192 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV100325575; called by muse, mutect2, varscan2
- ZBTB39 | c.1873C>T p.R625W | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs753292746, COSV55628592; called by muse, mutect2, varscan2
- ZNF142 | c.4798C>G p.L1600V (on ENST00000411696 / NM_001379660.1; = p.L1400V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV101376939; called by muse, mutect2, varscan2
- ZNF383 | c.140T>G p.L47R | Missense Mutation (SNP) | VAF 9/184 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.241); catalogued as COSV100776753; called by muse, mutect2
- ZNF518B | c.2971C>T p.R991C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1380410394, COSV100456712; called by muse, mutect2, varscan2
- ZNF585B | c.1387G>A p.E463K | Missense Mutation (SNP) | VAF 17/344 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); catalogued as COSV100459449; called by muse, mutect2
- ZNF804B | c.1669A>C p.S557R | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV100303811; called by muse, mutect2, varscan2
- FKBP6 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); called by muse, mutect2
- HEATR9 | c.985G>A p.V329I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.33); PolyPhen benign (0.063); called by muse, mutect2
- KNL1 | c.2627_2630del p.R876Kfs*30 (on ENST00000346991 / NM_170589.5; = p.R850Kfs*30 on NM_144508.5) | Frame Shift Del (DEL) | VAF 6/42 reads (14%) | called by pindel, varscan2
- NICN1 | c.615del p.Y205* | Frame Shift Del (DEL) | VAF 15/34 reads (44%) | called by mutect2, pindel, varscan2
- OR4K17 | c.535del p.C179Vfs*12 | Frame Shift Del (DEL) | VAF 16/165 reads (10%) | called by mutect2, pindel
- RUBCN | c.1337_1357+1del p.X446_splice | Splice Site (DEL) | VAF 9/40 reads (23%) | called by mutect2, pindel, varscan2
- VAV3 | c.1391dup p.W465Vfs*34 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | called by pindel, varscan2
- ZNF638 | c.4594_4597del p.P1532Yfs*16 | Frame Shift Del (DEL) | VAF 7/59 reads (12%) | called by mutect2, pindel
- AHNAK | c.2931C>T p.G977= | Silent (SNP) | VAF 25/132 reads (19%) | catalogued as COSV99947498; called by muse, mutect2, varscan2
- APOB | c.8412C>T p.L2804= | Silent (SNP) | VAF 31/151 reads (21%) | catalogued as rs762714613, COSV51934276, COSV99265629; called by muse, mutect2, varscan2
- ASIC2 | c.48C>T p.S16= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV100726388; called by muse, mutect2, varscan2
- B4GALNT3 | c.372G>A p.L124= | Silent (SNP) | VAF 10/91 reads (11%) | catalogued as rs1449504014, COSV99843036; called by mutect2, varscan2
- C2orf42 | c.576A>G p.K192= | Silent (SNP) | VAF 15/124 reads (12%) | catalogued as COSV100033896; called by muse, mutect2, varscan2
- FARP2 | c.1626G>A p.E542= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV99884635; called by muse, mutect2, varscan2
- FMNL2 | c.1149A>G p.E383= | Silent (SNP) | VAF 13/54 reads (24%) | catalogued as COSV99979694; called by muse, mutect2, varscan2
- FREM1 | c.1506C>T p.G502= | Silent (SNP) | VAF 13/315 reads (4%) | catalogued as COSV101084533; called by muse, mutect2
- GDF10 | c.1104G>A p.K368= | Silent (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- GRM8 | c.144G>A p.L48= | Silent (SNP) | VAF 16/111 reads (14%) | catalogued as COSV100282977, COSV58820098; called by muse, mutect2, varscan2
- H2AC16 | c.48G>A p.K16= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs781742626, COSV100511164, COSV100511246; called by muse, mutect2, varscan2
- IRF2 | c.150A>G p.K50= | Silent (SNP) | VAF 13/108 reads (12%) | catalogued as COSV101165816; called by muse, mutect2, varscan2
- ITPK1 | c.798C>T p.S266= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV99968503; called by muse, mutect2, varscan2
- MCF2 | c.1887C>G p.L629= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100644781; called by muse, mutect2, varscan2
- MDN1 | c.1950C>T p.F650= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs747347141, COSV65527772; called by muse, mutect2
- MRC1 | c.1611T>G p.A537= | Silent (SNP) | VAF 19/111 reads (17%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.102G>A p.T34= | Silent (SNP) | VAF 18/133 reads (14%) | catalogued as rs778729992, COSV66933169; called by muse, mutect2, varscan2
- MYO1F | c.462C>T p.F154= | Silent (SNP) | VAF 8/85 reads (9%) | catalogued as rs748272023, COSV57792991; called by muse, mutect2, varscan2
- POGK | c.501G>A p.G167= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV100902476; called by muse, mutect2, varscan2
- PXDN | c.2211C>T p.F737= | Silent (SNP) | VAF 24/116 reads (21%) | catalogued as COSV53245846, COSV99413489; called by muse, mutect2, varscan2
- PXDN | c.1761A>G p.A587= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99413495; called by muse, mutect2, varscan2
- RANBP17 | c.2595T>G p.A865= | Silent (SNP) | VAF 33/137 reads (24%) | catalogued as COSV101206265; called by muse, mutect2, varscan2
- RS1 | c.594C>T p.F198= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV101183809; called by muse, mutect2, varscan2
- SI | c.2913A>T p.A971= | Silent (SNP) | VAF 19/118 reads (16%) | catalogued as COSV100015555; called by muse, mutect2, varscan2
- SIPA1L2 | c.2718A>G p.G906= | Silent (SNP) | VAF 46/92 reads (50%) | catalogued as COSV99478255; called by muse, mutect2, varscan2
- SLC17A7 | c.1542C>T p.D514= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV99676839; called by muse, varscan2
- SLC22A12 | c.714T>C p.S238= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as rs1340366886, COSV100327655; called by muse, mutect2, varscan2
- SLC25A35 | c.222C>T p.F74= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV99873830; called by muse, mutect2, varscan2
- SMCP | c.45C>T p.G15= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs773280731, COSV64217614; called by muse, mutect2, varscan2
- SYNE1 | c.14703G>A p.R4901= (on ENST00000367255 / NM_182961.4; = p.R4830= on NM_033071.3) | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV55047496, COSV99564360; called by muse, mutect2, varscan2
- TMEM132D | c.1473C>A p.V491= | Silent (SNP) | VAF 7/39 reads (18%) | catalogued as COSV101242835; called by muse, mutect2, varscan2
- ZFHX4 | c.4911C>T p.S1637= | Silent (SNP) | VAF 4/49 reads (8%) | catalogued as COSV99262751; called by muse, mutect2
- ZIC1 | c.618G>A p.A206= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs1055126847, COSV51555849; called by muse, mutect2, varscan2
- ZP3 | c.1204C>T p.L402= (on ENST00000394857 / NM_001110354.2; = p.L351= on NM_007155.6) | Silent (SNP) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- DDX41 | c.*527A>G | 3'UTR (SNP) | VAF 12/83 reads (14%) | catalogued as COSV100394337; called by muse, mutect2, varscan2
- MIR891B | n.52G>A | RNA (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- RNU6-1191P | chr16:81109237 T>C | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2
